BEATAML1.0 case 2270 — Functional Genomic Landscape of Acute Myeloid Leukemia (BEATAML1.0-COHORT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/f48953aa-661b-4a2b-939c-d56bc0ce032b

Demographics
Sex at birth: female; Vital status: Dead.

Diagnoses (1)
1. Acute myeloid leukemia with t(6;9)(p23;q34), DEK-NUP214: ICD-O-3 morphology code: 9865/3; Tissue or organ of origin: Bone marrow; Age at diagnosis: 30.5 years (11,136 days); Progression or recurrence: no; ELN risk classification: Adverse.

Biospecimens (4 samples)
- Sample BA2050R: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Fresh.
- Sample BA2334D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
- Sample BA2334R: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Fresh.
- Sample BA2739D: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
